Somatic mutation profile of tumor specimen TCGA-QU-A6IM-01A (aliquot TCGA-QU-A6IM-01A-11D-A31L-08) from TCGA case TCGA-QU-A6IM, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.7 years (21,792 days).
Specimen TCGA-QU-A6IM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2eb6dd96-bcc2-4401-ba4a-349ee1abca1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QU-A6IM-10A (Blood Derived Normal), aliquot TCGA-QU-A6IM-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ce7ab13-ddc1-4046-b024-89cdeb82d697

The open-access MAF lists 69 somatic variants for this specimen: 55 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 12, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 32/74 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs1057519964, COSV61653339, COSV61655858; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs748398755, COSV50958076; called by muse, mutect2, varscan2
- A2ML1 | c.3461A>C p.N1154T | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV55289260; called by muse, mutect2, varscan2
- ARHGEF10L | c.174G>C p.E58D | Missense Mutation (SNP) | VAF 90/340 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.023); catalogued as COSV63418829; called by muse, mutect2, varscan2
- CADPS | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.93); catalogued as COSV51875749; called by muse, mutect2, varscan2
- CCT2 | c.736A>T p.T246S | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV54739827; called by muse, mutect2, varscan2
- CFAP65 | c.2542T>A p.W848R | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.063); catalogued as COSV58559943; called by muse, mutect2, varscan2
- CYP2C8 | c.1040A>G p.Y347C | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64876818; called by muse, mutect2, varscan2
- CYP4F12 | c.503A>C p.N168T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as COSV61173384; called by muse, mutect2, varscan2
- DOCK10 | c.5441A>T p.Y1814F | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV51377930; called by muse, mutect2, varscan2
- DOCK2 | c.5291T>A p.L1764Q | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.692); catalogued as COSV56953827; called by mutect2, varscan2
- EPHA7 | c.1265C>G p.S422C | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65181164; called by muse, varscan2
- FAM47A | c.894T>A p.C298* | Nonsense Mutation (SNP) | VAF 15/20 reads (75%) | catalogued as COSV60495849; called by muse, mutect2, varscan2
- FGF23 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 56/220 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1384170096, COSV52975192; called by muse, mutect2, varscan2
- FGFR2 | c.1689A>G p.I563M | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV60644959; called by muse, mutect2, varscan2
- GJA5 | c.367T>A p.Y123N | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.222); catalogued as COSV54783759; called by muse, mutect2, varscan2
- GRID1 | c.1631T>A p.L544Q | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60024276; called by muse, mutect2, varscan2
- HMCN1 | c.13051T>C p.F4351L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.942); catalogued as COSV54893575; called by muse, mutect2, varscan2
- IARS1 | c.647A>G p.E216G | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV65114824; called by muse, mutect2, varscan2
- INPP5B | c.2368A>G p.T790A (on ENST00000373023; = p.T710A on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.031); catalogued as COSV65960442; called by muse, mutect2, varscan2
- KCNIP1 | c.368T>A p.V123E (on ENST00000411494 / NM_001034837.3; = p.V112E on NM_014592.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61083470; called by muse, mutect2, varscan2
- KCNK5 | c.244A>T p.N82Y | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.134); catalogued as COSV63988799; called by muse, mutect2, varscan2
- LUZP1 | c.781C>A p.L261M | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV56500418; called by muse, mutect2, varscan2
- ME1 | c.78+1G>A p.X26_splice | Splice Site (SNP) | VAF 8/31 reads (26%) | catalogued as rs1175820458, COSV63838784; called by muse, mutect2
- MUC17 | c.6852A>G p.I2284M | Missense Mutation (SNP) | VAF 164/582 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV60286044; called by muse, mutect2, varscan2
- MYO18B | c.4322A>T p.D1441V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV59131588; called by muse, mutect2, varscan2
- MYOF | c.5984A>T p.K1995M | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV63702985; called by muse, mutect2, varscan2
- NCF2 | c.623T>A p.V208E | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62315197; called by muse, mutect2, varscan2
- NFATC1 | c.1469C>G p.A490G | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV53698926; called by muse, mutect2, varscan2
- NID2 | c.1250A>G p.N417S | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV53495210; called by muse, mutect2, varscan2
- NRG1 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV55155703, COSV55172943; called by muse, mutect2, varscan2
- NT5M | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs769139589, COSV66518743; called by muse, mutect2, varscan2
- NXPE1 | c.490T>A p.Y164N (on ENST00000424269; = p.Y22N on NM_152315.5) | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52628729; called by muse, mutect2, varscan2
- PHIP | c.340A>T p.S114C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV51503576; called by muse, mutect2, varscan2
- PLCH1 | c.3295A>G p.T1099A (on ENST00000340059 / NM_001130960.2; = p.T1091A on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV58193640; called by muse, mutect2, varscan2
- PPIAL4G | c.73T>G p.F25V | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV70086986; called by muse, mutect2, varscan2
- PTCHD4 | c.1142A>T p.Y381F | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.526); catalogued as COSV59782162; called by muse, mutect2, varscan2
- RPS11 | c.95A>C p.K32T | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV54526307; called by muse, mutect2, varscan2
- SIPA1L3 | c.4631C>T p.S1544L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs771877025, COSV55912576; called by muse, mutect2, varscan2
- SLAMF6 | c.163T>A p.W55R | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63586928; called by muse, mutect2, varscan2
- TEKT3 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV58627201; called by muse, mutect2, varscan2
- TMPRSS7 | c.2213G>A p.R738K (on ENST00000452346; = p.R612K on NM_001042575.2) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV69980359; called by muse, mutect2, varscan2
- TRA2A | c.171-2A>T p.X57_splice | Splice Site (SNP) | VAF 31/60 reads (52%) | catalogued as COSV51716627; called by muse, mutect2, varscan2
- TRUB2 | c.962C>G p.S321C | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); catalogued as rs762738903, COSV65759563; called by muse, mutect2, varscan2
- UBR2 | c.5077T>G p.Y1693D | Missense Mutation (SNP) | VAF 142/489 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV65749045, COSV65749807; called by muse, mutect2, varscan2
- USH2A | c.5819T>C p.V1940A | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV56357872; called by muse, mutect2, varscan2
- VEPH1 | c.1541T>C p.I514T | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV62878162; called by muse, mutect2, varscan2
- XKR3 | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV58885737; called by muse, mutect2, varscan2
- ZEB1 | c.1215A>G p.I405M | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV58042076; called by muse, mutect2, varscan2
- ZNF462 | c.5530C>G p.L1844V | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV52935990; called by muse, mutect2, varscan2
- ZNF470 | c.1693T>G p.Y565D | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57968540; called by muse, mutect2, varscan2
- ZNF98 | c.308A>T p.Y103F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV63335958; called by muse, mutect2, varscan2
- CPLX4 | c.19del p.S7Vfs*2 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel
- DERL2 | c.601del p.T201Hfs*5 | Frame Shift Del (DEL) | VAF 23/104 reads (22%) | called by mutect2, pindel, varscan2
- STRC | c.4307del p.P1436Hfs*11 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- ATXN2 | c.1752G>T p.P584= (on ENST00000550104; = p.P424= on NM_002973.4) | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV66482675; called by muse, mutect2, varscan2
- CARD6 | c.1702C>T p.L568= | Silent (SNP) | VAF 9/159 reads (6%) | catalogued as COSV54565694; called by muse, mutect2
- CXADR | c.405G>T p.L135= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV53028760; called by muse, mutect2
- DHFR | c.282A>G p.L94= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs1331762283, COSV71485510; called by muse, mutect2, varscan2
- FAM13A | c.1422A>G p.K474= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as COSV52001035; called by muse, mutect2, varscan2
- OR1G1 | c.150T>A p.I50= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as COSV61030060; called by muse, mutect2, varscan2
- SLC25A17 | c.729A>G p.T243= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs747563677, COSV54351070; called by muse, mutect2, varscan2
- SLC41A1 | c.600C>A p.V200= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV65650374, COSV65651824; called by muse, mutect2, varscan2
- TAAR9 | c.1005G>A p.S335= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs370306299, COSV71512218; called by muse, mutect2, varscan2
- TENM2 | c.1407A>G p.S469= (on ENST00000518659 / NM_001122679.2; = p.S237= on NM_001080428.3) | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV69127995; called by muse, mutect2, varscan2
- UBR2 | c.4725C>T p.C1575= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs1477640434; called by muse, mutect2
- WFDC6 | c.84C>T p.I28= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV60548463; called by muse, mutect2
- AC024598.1 | c.1130-12467T>A | Intron (SNP) | VAF 16/102 reads (16%) | catalogued as COSV60823911; called by muse, mutect2, varscan2
- UBTFL2 | n.282A>T | RNA (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
